Somatic mutation profile of tumor specimen TCGA-DU-7294-01A (aliquot TCGA-DU-7294-01A-11D-2024-08) from TCGA case TCGA-DU-7294, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 53.7 years (19,616 days).
Specimen TCGA-DU-7294-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f96999c7-f122-4dcc-99e1-64f3ce577502.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-7294-10A (Blood Derived Normal), aliquot TCGA-DU-7294-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b69acd4a-8fca-466f-9f90-fa3b4c45747c

The open-access MAF lists 28 somatic variants for this specimen: 18 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 9, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 39/92 reads (42%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by mutect2, varscan2
- CIC | c.701T>A p.L234Q | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50564083; called by muse, mutect2, varscan2
- CLEC7A | c.479G>A p.S160N (on ENST00000304084 / NM_197947.3; = p.S114N on NM_022570.5) | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as rs748327912, COSV53722193; called by muse, mutect2, varscan2
- COBLL1 | c.805A>G p.I269V (on ENST00000392717; = p.I231V on NM_014900.5) | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.63); PolyPhen benign (0.068); catalogued as COSV52067193, COSV52071969; called by muse, mutect2, varscan2
- EXD1 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV59253922; called by muse, mutect2, varscan2
- HDX | c.1315C>A p.R439S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52976198, COSV52983078; called by muse, mutect2, varscan2
- MAGEE2 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV64897625; called by mutect2, varscan2
- MMEL1 | c.1255C>T p.R419* | Nonsense Mutation (SNP) | VAF 32/43 reads (74%) | catalogued as rs757779072, COSV56521131; called by mutect2, varscan2
- NPAP1 | c.3383G>C p.W1128S | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); catalogued as COSV61506477; called by muse, mutect2, varscan2
- OR52N5 | c.644T>C p.I215T | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.72); catalogued as COSV57698794; called by muse, mutect2, varscan2
- PSMD5 | c.837C>A p.N279K | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.911); catalogued as COSV52960606; called by muse, mutect2, varscan2
- RNF32 | c.404A>G p.E135G | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV58732184; called by muse, mutect2
- SH2B3 | c.1099G>A p.G367S | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765614074, COSV57981830; called by muse, mutect2, varscan2
- SMARCA4 | c.3502G>C p.A1168P | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60791929, COSV60793226, COSV60804175; called by muse, mutect2
- TANGO6 | c.440T>C p.F147S | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55764544; called by muse, mutect2, varscan2
- TLR7 | c.566G>C p.C189S | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66124211; called by muse, mutect2, varscan2
- TPM3 | c.392T>C p.I131T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV55135907; called by muse, mutect2, varscan2
- USP37 | c.2681T>G p.V894G | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV50287423; called by muse, mutect2
- CABLES1 | c.1860C>T p.H620= (on ENST00000256925 / NM_001100619.2; = p.H355= on NM_138375.2) | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs777583651, COSV56930318; called by mutect2, varscan2
- DMPK | c.1296C>T p.H432= | Silent (SNP) | VAF 20/24 reads (83%) | catalogued as rs775509391, COSV52177699; called by mutect2, varscan2
- GGT7 | c.1701G>A p.A567= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs780921464, COSV60540710; called by mutect2, varscan2
- MAGI2 | c.1059C>G p.G353= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV62653213; called by muse, mutect2, varscan2
- PCLO | c.7008C>T p.S2336= | Silent (SNP) | VAF 47/95 reads (49%) | catalogued as rs181143686; called by muse, mutect2, varscan2
- POP1 | c.2439G>A p.K813= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV62892600; called by muse, mutect2
- TMEM131 | c.5094C>T p.S1698= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV51774956; called by mutect2, varscan2
- TMEM176A | c.492C>A p.P164= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs754927423, COSV50240985; called by muse, mutect2, varscan2
- TRPC6 | c.2736T>C p.L912= | Silent (SNP) | VAF 50/145 reads (34%) | catalogued as COSV60254025; called by muse, mutect2, varscan2
- COL6A2 | c.2462-2498G>A | Intron (SNP) | VAF 8/27 reads (30%) | catalogued as rs770153478, COSV100153347; called by mutect2, varscan2
